Gene-level copy-number profile of tumor specimen TCGA-EO-A2CH-01A from TCGA case TCGA-EO-A2CH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 73.8 years (26,966 days).
Specimen TCGA-EO-A2CH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.453a93db-c5f0-49df-92ae-03906adb4f37.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EO-A2CH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a79fa932-c308-4c97-8940-ec6055feacb2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 32; copy number 2: 9,735; copy number 3: 4,802; copy number 4: 38,911; copy number 5: 775; copy number 6: 4,546; copy number 7: 260; copy number 8: 3; copy number 9: 361; copy number 10: 15; copy number 11: 88; copy number 13: 38; copy number 15: 77; copy number 17: 40; copy number 18: 95; copy number 22: 8; copy number 28: 5; copy number 46: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EO-A2CH-01A-11D-A17U-01): tumor purity 0.87, ploidy 3.94, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:75,089,248–75,182,123, 4 genes: PPIAP13, DUSP13, SAMD8, RPS26P42.
- chr10:87,500,337–87,971,930, 14 genes (within-gene range 0–2): AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 728 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:146,879,909–147,810,777, 7 genes, copy number 9 (within-gene range 4–9): AC062032.1, AC018678.1, RNU6-692P, Y_RNA, RNU6-715P, RNA5SP106, AC009480.2.
- chr8:113,376,669–138,083,657, 300 genes, copy number 11–46 (broad region; genes not listed).
- chr10:60,684,505–63,658,521, 38 genes, copy number 13: ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1.
- chr10:70,389,426–70,568,450, 6 genes, copy number 9 (within-gene range 2–9): CEP57L1P1, EIF4EBP2, NODAL, AC022532.1, PALD1, YY1P1.
- chr13:94,154,193–94,187,991, 1 gene, copy number 22: GPC6-AS1.
- chr16:70,523,791–70,801,160, 13 genes, copy number 15 (within-gene range 2–15): SF3B3, SNORD111B, SNORD111, IL34, MTSS2, AC020763.4, VAC14, AC020763.3, AC020763.1, VAC14-AS1, AC020763.5, AC020763.2, AC027281.1.
- chr17:27,878,314–29,404,105, 105 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr17:29,390,662–29,390,730, 1 gene, copy number 9: MIR4523.
- chr17:30,378,927–30,672,789, 15 genes, copy number 10 (within-gene range 2–10): CPD, GOSR1, ALOX12P1, AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2, KRT17P3, AC011840.1, AC005562.1, SMURF2P1, AC005562.2, SH3GL1P2, LRRC37BP1.
- chr17:48,874,860–50,397,888, 83 genes, copy number 9 (broad region; genes not listed).
- chr17:50,503,412–52,160,017, 43 genes, copy number 9 (within-gene range 6–9): AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3, AC004590.1, ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1.
- chr17:59,962,363–63,611,184, 115 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr17:63,636,601–63,637,113, 1 gene, copy number 9: EEF1DP7.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
